Somatic mutation profile of tumor specimen TCGA-IB-7654-01A (aliquot TCGA-IB-7654-01A-11D-2154-08) from TCGA case TCGA-IB-7654, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.2 years (29,292 days).
Specimen TCGA-IB-7654-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc689b12-1715-4321-9c6d-4180554b4291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7654-10A (Blood Derived Normal), aliquot TCGA-IB-7654-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaf7b62f-8e0f-4e74-8225-70231a13c5e6

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 25, Silent 12, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 17/115 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 49/210 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDC20 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 73/341 reads (21%) | catalogued as COSV100196334; called by muse, mutect2, varscan2
- CDH20 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 109/401 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs762896499, COSV53010082, COSV53016279; called by muse, mutect2, varscan2
- CRPPA | c.982C>T p.Q328* (on ENST00000407010 / NM_001368197.1; = p.Q278* on NM_001101417.4) | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | catalogued as COSV101235313; called by muse, mutect2
- CYP11A1 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 101/634 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs974871680, COSV51430685; called by muse, mutect2, varscan2
- DIRAS3 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 70/378 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100921302; called by muse, mutect2, varscan2
- EIF4E1B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs1296660855, COSV53781927; called by muse, mutect2
- EPHA10 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 220/2360 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.231); catalogued as COSV100139787; called by muse, mutect2
- FOXF1 | c.462G>T p.M154I | Missense Mutation (SNP) | VAF 134/717 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99296368; called by muse, mutect2, varscan2
- GPR132 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 84/413 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs778976347, COSV61677560, COSV61677833; called by muse, mutect2, varscan2
- H2BC4 | c.43T>A p.S15T | Missense Mutation (SNP) | VAF 163/839 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.113); catalogued as COSV100019763; called by muse, mutect2, varscan2
- IGHG4 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 113/838 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs370809726; called by muse, mutect2, varscan2
- KCNA5 | c.825C>A p.F275L | Missense Mutation (SNP) | VAF 169/2340 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.263); catalogued as rs866280456, COSV99363671; called by muse, mutect2
- KIF24 | c.3121C>G p.H1041D | Missense Mutation (SNP) | VAF 81/492 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99902892; called by muse, mutect2, varscan2
- MTUS2 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 113/582 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs371733167; called by muse, mutect2, varscan2
- OR2T3 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1284758963, COSV100613102; called by muse, mutect2, varscan2
- OR4C6 | c.769A>G p.M257V | Missense Mutation (SNP) | VAF 117/714 reads (16%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.003); catalogued as rs749468804, COSV100051429; called by muse, mutect2, varscan2
- PCSK2 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 101/665 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs755466922, COSV99358804; called by muse, mutect2, varscan2
- PNPLA7 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); catalogued as rs140172154; called by muse, varscan2
- PRAMEF19 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 132/812 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1283247596; called by muse, varscan2
- ROBO3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs768314789, COSV67299357; called by muse, mutect2, varscan2
- SLC26A1 | c.349A>T p.T117S | Missense Mutation (SNP) | VAF 170/952 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99925719; called by muse, mutect2, varscan2
- SMG9 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 120/620 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1568382956, COSV54215284; called by muse, mutect2, varscan2
- TMEM108 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs149789292; called by muse, mutect2, varscan2
- TRPS1 | c.2977C>G p.Q993E (on ENST00000220888 / NM_001330599.2; = p.Q1006E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/732 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV99628758; called by muse, mutect2
- CTNND1 | c.665dup p.G223Rfs*4 | Frame Shift Ins (INS) | VAF 139/877 reads (16%) | called by mutect2, pindel, varscan2
- DEK | c.990_993del p.K330Nfs*13 | Frame Shift Del (DEL) | VAF 66/402 reads (16%) | called by mutect2, pindel, varscan2
- PPP2R3A | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2
- CDCA8 | c.642C>T p.I214= | Silent (SNP) | VAF 184/549 reads (34%) | catalogued as COSV100523519; called by muse, mutect2, varscan2
- FUT1 | c.711C>T p.G237= | Silent (SNP) | VAF 163/807 reads (20%) | catalogued as COSV59567506; called by muse, mutect2, varscan2
- GLI2 | c.4227G>A p.S1409= (on ENST00000361492 / NM_001374353.1; = p.S1426= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/417 reads (21%) | catalogued as rs143388073, COSV58045388; called by muse, mutect2, varscan2
- GRIN2A | c.423G>A p.T141= | Silent (SNP) | VAF 48/435 reads (11%) | catalogued as rs527558415, COSV58018805, COSV58020826; called by muse, mutect2, varscan2
- KRT17 | c.1167G>A p.E389= | Silent (SNP) | VAF 62/489 reads (13%) | catalogued as rs1478674225, COSV100245061, COSV100245088; called by muse, mutect2, varscan2
- NAT10 | c.2583G>A p.A861= | Silent (SNP) | VAF 34/202 reads (17%) | catalogued as rs374547624; called by muse, mutect2, varscan2
- NTF4 | c.597C>T p.C199= | Silent (SNP) | VAF 66/373 reads (18%) | catalogued as rs765132008, COSV56824718; called by muse, mutect2, varscan2
- OR2F1 | c.348G>A p.A116= | Silent (SNP) | VAF 104/802 reads (13%) | catalogued as rs780796034, COSV67332309; called by muse, mutect2, varscan2
- SLC6A13 | c.513C>A p.S171= | Silent (SNP) | VAF 1154/1392 reads (83%) | catalogued as COSV100569776; called by muse, varscan2
- TRPM6 | c.1923G>A p.A641= | Silent (SNP) | VAF 91/386 reads (24%) | catalogued as rs372508531; called by muse, mutect2, varscan2
- ZNF304 | c.1695G>A p.G565= | Silent (SNP) | VAF 49/315 reads (16%) | catalogued as COSV99988419; called by muse, mutect2, varscan2
- ZSCAN18 | c.936C>T p.D312= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs779069148, COSV99559150; called by muse, mutect2, varscan2
